Somatic mutation profile of tumor specimen TCGA-BT-A2LA-01A (aliquot TCGA-BT-A2LA-01A-11D-A18F-08) from TCGA case TCGA-BT-A2LA, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 54.8 years (20,032 days).
Specimen TCGA-BT-A2LA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee32558d-68c2-4555-996a-fc0bafac2e38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A2LA-11A (Solid Tissue Normal), aliquot TCGA-BT-A2LA-11A-11D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d7c2967-5428-464f-865e-9b9464c5bcf4

The open-access MAF lists 184 somatic variants for this specimen: 130 protein-altering or splice-affecting, 46 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 46, Nonsense Mutation 11, Intron 4, Splice Site 4, Frame Shift Ins 2, 5'UTR 2, Splice Region 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSL | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs122460152, CM950099, COSV66964820; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.2548C>T p.Q850* | Nonsense Mutation (SNP) | VAF 32/35 reads (91%) | catalogued as rs886042935, COSV57296102; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 24/25 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AANAT | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs535773364, COSV51685053; called by muse, mutect2, varscan2
- ABCD1 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT tolerated (0.41); PolyPhen benign (0.101); catalogued as COSV54385161; called by muse, mutect2, varscan2
- ABCD1 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 22/22 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV54385169; called by muse, mutect2, varscan2
- ABCF3 | c.656T>C p.L219S | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53048497; called by muse, mutect2, varscan2
- ABL1 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59332535, COSV59333242; called by muse, mutect2, varscan2
- ADGRL3 | c.1069C>T p.Q357* (on ENST00000506720 / NM_001322402.2; = p.Q289* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 27/36 reads (75%) | catalogued as COSV101547217, COSV72270438; called by muse, mutect2, varscan2
- AKAP5 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 66/99 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1381789447, COSV57742524; called by muse, mutect2, varscan2
- ANKRD2 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs375124321; called by muse, mutect2, varscan2
- ARMC2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as COSV52900556; called by muse, varscan2
- BEST4 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 59/294 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.456); catalogued as COSV64734025; called by muse, mutect2, varscan2
- BNC2 | c.3179G>C p.R1060T | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66167038, COSV66171021; called by muse, mutect2, varscan2
- BPIFB6 | c.1143-1G>A p.X381_splice | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100848541; called by mutect2, varscan2
- C1orf127 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs755373283, COSV65437588; called by muse, mutect2, varscan2
- C1orf159 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs553427569, COSV53881347; called by muse, mutect2, varscan2
- CAPN1 | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0.299); catalogued as rs758850643, COSV54199123; called by muse, mutect2, varscan2
- CASQ2 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54771119; called by muse, mutect2, varscan2
- CBR4 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60370253; called by muse, mutect2, varscan2
- CDC42BPA | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62012543, COSV62017223; called by muse, mutect2, varscan2
- CDH18 | c.2030G>A p.R677K | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as COSV56900908, COSV56928101; called by muse, mutect2, varscan2
- CFAP44 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55612178; called by muse, mutect2, varscan2
- CILK1 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV63154456; called by muse, mutect2, varscan2
- CLN3 | c.346G>A p.V116I (on ENST00000360019 / NM_001286104.2; = p.V140I on NM_000086.2) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs373034150; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CMTM2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.045); catalogued as rs761636615, COSV51748921; called by mutect2, varscan2
- CNDP1 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV62594095; called by muse, mutect2, varscan2
- COL6A2 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56007190; called by muse, mutect2, varscan2
- COL6A6 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as COSV62027295; called by muse, varscan2
- CPA6 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1286752731, COSV52731704; called by muse, mutect2, varscan2
- CPS1 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV51812580; called by muse, mutect2, varscan2
- CSMD1 | c.10433C>A p.S3478Y (on ENST00000520002; = p.S3477Y on NM_033225.6) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs1237976652; called by muse, mutect2
- CUL5 | c.2185A>G p.I729V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV67609126; called by muse, mutect2
- CWF19L1 | c.1001G>T p.S334I | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62499380; called by muse, mutect2, varscan2
- DLAT | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99734849; called by muse, mutect2
- DMXL1 | c.8809G>A p.D2937N | Missense Mutation (SNP) | VAF 58/79 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60713409; called by muse, mutect2, varscan2
- DNAH1 | c.11153G>A p.R3718H | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs371451336; called by muse, mutect2, varscan2
- DNAJC14 | c.1296G>C p.L432F | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57913188; called by muse, mutect2, varscan2
- DSTYK | c.1144C>G p.R382G | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65686833; called by muse, mutect2, varscan2
- DYSF | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs761279290, COSV50445122; called by muse, mutect2, varscan2
- ENPP7 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV60386843; called by muse, mutect2
- EPOR | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs576644426, COSV55800552; called by muse, mutect2, varscan2
- EXOSC10 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481374464, COSV58665836; called by muse, mutect2, varscan2
- EYA4 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as COSV62053586; called by muse, mutect2, varscan2
- FAM222A | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs537650643, COSV62723471; called by muse, mutect2, varscan2
- FCGBP | c.6587G>A p.R2196H | Missense Mutation (SNP) | VAF 56/2408 reads (2%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1219193234, COSV99663142; called by muse, mutect2
- FER1L6 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs376735300, COSV67550495; called by muse, mutect2, varscan2
- FLACC1 | c.956G>A p.R319K | Missense Mutation (SNP) | VAF 45/45 reads (100%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.164); catalogued as rs756241097, COSV51852361; called by muse, mutect2, varscan2
- FLG | c.3250C>T p.Q1084* | Nonsense Mutation (SNP) | VAF 162/722 reads (22%) | catalogued as rs758675000, COSV64245500; called by muse, mutect2, varscan2
- FTCD | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 5/92 reads (5%) | catalogued as rs140217223; ClinVar: uncertain significance; called by muse, mutect2
- GABRR1 | c.748A>C p.I250L | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as COSV65619618; called by muse, mutect2, varscan2
- GLI4 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV60682154, COSV60682519; called by muse, mutect2, varscan2
- GLRA2 | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54342039; called by muse, mutect2, varscan2
- GPC6 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as rs772667427, COSV100989478, COSV100989970; called by muse, mutect2
- GPX3 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as rs769489466, COSV59307423; called by muse, mutect2, varscan2
- HECTD1 | c.7291A>T p.S2431C | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV67946766; called by muse, mutect2, varscan2
- HECTD4 | c.3260G>T p.G1087V | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV61179770; called by muse, mutect2, varscan2
- HNF1A | c.1332G>C p.Q444H | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57460076; called by muse, mutect2, varscan2
- HPGD | c.391G>A p.G131S | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772802646, COSV56662971; called by muse, mutect2, varscan2
- HRCT1 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs140751149; called by muse, mutect2, varscan2
- HSF4 | c.189C>G p.F63L | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50457580; called by muse, varscan2
- HSPH1 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100185048; called by muse, mutect2
- ILK | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as rs1359613816, COSV54449836; called by muse, mutect2, varscan2
- ITGA2B | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV52232695; called by muse, mutect2, varscan2
- KRTAP10-7 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as rs1306863378, COSV59110769; called by muse, mutect2, varscan2
- LPIN1 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1368552319, COSV56766346; called by muse, mutect2, varscan2
- LRP2 | c.9550C>T p.R3184* | Nonsense Mutation (SNP) | VAF 56/122 reads (46%) | catalogued as CM124418; called by muse, mutect2, varscan2
- LTBP1 | c.1952C>T p.T651I (on ENST00000404816 / NM_206943.4; = p.T325I on NM_000627.4) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV63189125; called by muse, mutect2, varscan2
- LY75 | c.4433C>A p.P1478Q | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV55105327, COSV55107180; called by muse, mutect2, varscan2
- MAGI1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.062); catalogued as COSV58329990; called by muse, mutect2, varscan2
- MAST3 | c.2276G>A p.G759E | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.07); catalogued as COSV53218675; called by muse, varscan2
- MAST3 | c.2380G>C p.E794Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV53221698, COSV99445983; called by muse, varscan2
- MCM3AP | c.2180C>T p.T727M | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771535999, COSV52440718; called by muse, mutect2, varscan2
- MCM3AP | c.2179A>T p.T727S | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52440728; called by muse, mutect2, varscan2
- MMEL1 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | catalogued as rs1435406847, COSV56522287, COSV56525020; called by muse, mutect2, varscan2
- MORC1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as COSV51721573; called by muse, mutect2, varscan2
- MST1R | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.261); catalogued as rs923422767, COSV56569702; called by muse, mutect2, varscan2
- MTA1 | c.1691C>T p.T564M | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.587); catalogued as rs782209168, COSV58756459; called by muse, mutect2, varscan2
- MYH7 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as CM033412, COSV62518580, COSV62520090; called by muse, mutect2, varscan2
- NEB | c.4264G>C p.E1422Q | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.995); catalogued as rs921972170, COSV50817243, COSV51423602; called by muse, mutect2, varscan2
- NOC3L | c.1906C>T p.H636Y | Missense Mutation (SNP) | VAF 49/49 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs946507893, COSV64929997; called by muse, mutect2, varscan2
- NXPH1 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748850462, COSV68314357; called by muse, mutect2, varscan2
- PARP12 | c.1693G>A p.G565S | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441758501, COSV54933162; called by muse, mutect2, varscan2
- PBRM1 | c.3973G>A p.D1325N (on ENST00000296302 / NM_001366071.2; = p.D1300N on NM_018313.5) | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV56276343; called by muse, mutect2, varscan2
- PCMTD2 | c.706+1G>A p.X236_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | catalogued as rs1281403174, COSV55060689; called by muse, mutect2, varscan2
- PIK3AP1 | c.1398T>A p.S466R | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.165); catalogued as COSV59533402; called by muse, mutect2, varscan2
- PLCXD3 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100125797, COSV60610033; called by muse, mutect2, varscan2
- PLEC | c.6754G>A p.E2252K (on ENST00000322810 / NM_201380.4; = p.E2142K on NM_000445.5) | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as rs782713908, COSV59640479; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXND1 | c.5654G>A p.R1885Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as rs369952557; called by muse, mutect2, varscan2
- POLR2I | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 86/283 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as COSV52900366; called by muse, mutect2, varscan2
- PRKCI | c.826dup p.T276Nfs*16 | Frame Shift Ins (INS) | VAF 16/60 reads (27%) | catalogued as rs753143066; called by mutect2, varscan2
- PTPDC1 | c.196G>C p.E66Q (on ENST00000375360 / NM_177995.3; = p.E118Q on NM_152422.4) | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV56623706; called by muse, mutect2, varscan2
- PTPN4 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.98); catalogued as COSV55302721, COSV99749982; called by muse, mutect2, varscan2
- QTRT2 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55560379; called by muse, mutect2, varscan2
- RABL6 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs779589434, COSV61032756; called by muse, mutect2, varscan2
- RANBP17 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 68/104 reads (65%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV66651423, COSV66654792; called by muse, mutect2, varscan2
- RANBP2 | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV51702367; called by muse, mutect2, varscan2
- RBM26 | c.2974G>C p.D992H (on ENST00000438737 / NM_001366735.2; = p.D965H on NM_022118.5) | Missense Mutation (SNP) | VAF 51/76 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV57395365; called by muse, mutect2, varscan2
- RCOR3 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1269490330, COSV65365965; called by muse, mutect2, varscan2
- RNF144A | c.482C>G p.P161R | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.358); catalogued as rs765223317, COSV57982983; called by muse, mutect2, varscan2
- RNF17 | c.2014A>G p.I672V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55041851; called by muse, mutect2
- RNF40 | c.2830-1G>A p.X944_splice | Splice Site (SNP) | VAF 34/235 reads (14%) | catalogued as COSV52698826; called by muse, mutect2, varscan2
- SELENON | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 65/331 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.158); catalogued as COSV62524963; called by muse, mutect2, varscan2
- SIGLEC11 | c.1652-1G>A p.X551_splice | Splice Site (SNP) | VAF 33/35 reads (94%) | catalogued as COSV68567728; called by muse, mutect2, varscan2
- SLC39A11 | c.1018G>T p.G340C (on ENST00000542342 / NM_001159770.2; = p.G333C on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55290623; called by muse, varscan2
- SLC7A10 | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV53504653; called by muse, mutect2, varscan2
- SMAD1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV57471634; called by muse, mutect2, varscan2
- SMURF2 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV52315975; called by muse, mutect2, varscan2
- SNIP1 | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56166907; called by muse, mutect2, varscan2
- SORBS3 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53551836; called by muse, mutect2, varscan2
- SPECC1 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs371567265; called by muse, mutect2, varscan2
- SPIRE1 | c.1276A>G p.M426V (on ENST00000409402 / NM_001128626.2; = p.M412V on NM_020148.3) | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs754100028, COSV59157298; called by muse, mutect2, varscan2
- SVOPL | c.1378G>C p.G460R (on ENST00000419765; = p.G308R on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.806); catalogued as COSV55990558, COSV55991935; called by muse, mutect2
- SYTL1 | c.1548C>T p.T516= (on ENST00000543823; = p.T504= on NM_032872.3) | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as rs753718528; called by muse, mutect2
- TMEM184A | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV52473833; called by muse, mutect2, varscan2
- TNFRSF19 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 69/73 reads (95%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.463); catalogued as rs146263697, COSV50317013; called by muse, mutect2, varscan2
- TNFSF8 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145748228; called by muse, mutect2, varscan2
- TNNT3 | c.550G>A p.E184K (on ENST00000397301 / NM_001367846.1; = p.E173K on NM_006757.4) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99548630; called by muse, mutect2, varscan2
- UBE4A | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV52804522; called by muse, mutect2, varscan2
- UBTF | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 13/15 reads (87%) | PolyPhen benign (0); catalogued as COSV57186580; called by mutect2, varscan2
- UGT2B10 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 63/196 reads (32%) | catalogued as rs754651977, COSV99608695; called by muse, mutect2, varscan2
- UTRN | c.6879G>C p.L2293F | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62337499; called by muse, mutect2, varscan2
- VPS13B | c.9945G>C p.L3315F | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV62144906; called by muse, mutect2, varscan2
- YY1AP1 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.5); catalogued as COSV55120571, COSV55122662; called by muse, varscan2
- CEP170 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- JAG2 | c.2978C>G p.S993C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); called by muse, mutect2
- MIDEAS | c.1411dup p.Q471Pfs*19 | Frame Shift Ins (INS) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- MN1 | c.2743G>A p.G915S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by muse, mutect2
- SAMD4A | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- SYNE1 | c.23059G>T p.E7687* (on ENST00000367255 / NM_182961.4; = p.E7616* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.171G>A p.T57= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as rs778448758, COSV63204671; called by muse, mutect2, varscan2
- ADGRL3 | c.3363G>A p.L1121= (on ENST00000506720 / NM_001322402.2; = p.L1053= on NM_015236.6) | Silent (SNP) | VAF 36/47 reads (77%) | catalogued as COSV72230814; called by muse, mutect2, varscan2
- C5orf46 | c.24G>C p.L8= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV59154089; called by muse, mutect2, varscan2
- CAPN5 | c.384G>A p.S128= (on ENST00000456580; = p.S88= on NM_004055.5) | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs199875193, COSV53688605; called by muse, mutect2, varscan2
- CDAN1 | c.2775C>T p.H925= | Silent (SNP) | VAF 44/118 reads (37%) | catalogued as rs201778116, COSV62330722; called by muse, mutect2, varscan2
- CDH15 | c.1806C>T p.L602= | Silent (SNP) | VAF 8/10 reads (80%) | called by muse, mutect2, varscan2
- COL6A6 | c.465G>A p.R155= | Silent (SNP) | VAF 46/88 reads (52%) | catalogued as COSV62027313; called by muse, varscan2
- CPAMD8 | c.1377C>A p.I459= (on ENST00000651564; = p.I412= on NM_015692.5) | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV52235449; called by muse, mutect2, varscan2
- CREB3L3 | c.882G>A p.K294= | Silent (SNP) | VAF 45/100 reads (45%) | catalogued as COSV50210152; called by muse, mutect2, varscan2
- CTU1 | c.711C>T p.C237= | Silent (SNP) | VAF 19/20 reads (95%) | catalogued as rs1209852806, COSV70292471; called by muse, varscan2
- DEF8 | c.105C>T p.L35= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as rs750808131, COSV51919502; called by muse, mutect2, varscan2
- DHRS4L2 | c.243G>A p.L81= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs1052728921, COSV58729930; called by muse, mutect2, varscan2
- DMWD | c.747G>A p.S249= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs756878223, COSV52179038; called by muse, mutect2, varscan2
- DONSON | c.1368G>A p.V456= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV51660002; called by muse, mutect2, varscan2
- EFCAB6 | c.2631C>T p.Y877= | Silent (SNP) | VAF 37/51 reads (73%) | catalogued as rs771801224, COSV53064968; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.57G>A p.K19= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs775297533, COSV57516344; called by muse, mutect2, varscan2
- ENPP7 | c.405G>C p.L135= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV60386835; called by muse, mutect2, varscan2
- ENPP7 | c.633G>A p.E211= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs374642136; called by muse, mutect2
- FANCC | c.720C>G p.V240= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV56661469; called by muse, mutect2, varscan2
- FCGBP | c.2751G>A p.V917= | Silent (SNP) | VAF 50/281 reads (18%) | called by muse, mutect2, varscan2
- FPGT | c.1701C>T p.F567= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV63841338; called by muse, mutect2, varscan2
- FRMPD3 | c.4896C>T p.N1632= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as rs765564425, COSV52191386; called by muse, mutect2, varscan2
- GAK | c.3840G>A p.A1280= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs773959957, COSV58505509; called by muse, mutect2, varscan2
- GMIP | c.2259C>T p.Y753= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as rs373163906; called by muse, mutect2, varscan2
- GPD1L | c.624C>T p.I208= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs267599768, COSV56990163, COSV56992719; called by muse, mutect2
- GPSM1 | c.105C>T p.G35= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs1554768900, COSV61304382; called by muse, mutect2, varscan2
- MAP4K1 | c.1122A>T p.S374= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV67710817; called by muse, mutect2, varscan2
- MMEL1 | c.2187C>T p.P729= | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as COSV56522209, COSV99983190; called by muse, mutect2, varscan2
- MZF1 | c.1716C>T p.A572= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs1227865196, COSV53041649; called by muse, mutect2
- NAPG | c.39C>T p.L13= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs1212648097, COSV59797295; called by muse, mutect2, varscan2
- NOSIP | c.822C>T p.I274= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as rs781321147, COSV59199013; called by muse, mutect2, varscan2
- PIK3R2 | c.426C>T p.S142= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs1218852326, COSV55848360; called by muse, mutect2, varscan2
- PLEKHG2 | c.678G>A p.S226= | Silent (SNP) | VAF 37/340 reads (11%) | catalogued as rs756829121, COSV52684952; called by muse, mutect2, varscan2
- PPP2CA | c.393T>C p.D131= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV51538298; called by muse, mutect2, varscan2
- PRKCE | c.687C>T p.P229= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs759793988, COSV60320481; called by muse, mutect2
- PSKH1 | c.156C>T p.F52= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs200502249, COSV52123743; called by muse, mutect2, varscan2
- RBL2 | c.1431C>T p.D477= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs138458893; called by muse, mutect2, varscan2
- SLC4A2 | c.3456C>G p.V1152= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as COSV52540417; called by muse, mutect2, varscan2
- SULT4A1 | c.249C>T p.D83= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as rs901703458, COSV50781448, COSV99970670; called by muse, mutect2, varscan2
- THOP1 | c.1398C>T p.D466= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs373754322; called by muse, mutect2, varscan2
- TNKS1BP1 | c.468C>T p.F156= | Silent (SNP) | VAF 72/148 reads (49%) | catalogued as rs546086969, COSV64100475; called by muse, mutect2, varscan2
- VWA2 | c.1932C>T p.G644= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs376160370; called by muse, mutect2, varscan2
- WWC1 | c.1863C>T p.A621= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs764998317, COSV54650132; called by muse, mutect2, varscan2
- ZNF333 | c.1881C>T p.F627= | Silent (SNP) | VAF 89/179 reads (50%) | catalogued as rs376867404, COSV52886515, COSV99469331; called by muse, mutect2, varscan2
- ZNF436 | c.18C>T p.L6= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs1239105441, COSV58358697; called by muse, mutect2, varscan2
- ZNF536 | c.978C>T p.A326= | Silent (SNP) | VAF 49/487 reads (10%) | catalogued as rs536835285, COSV62819788; called by muse, mutect2, varscan2
- BANP | c.163-19C>T | Intron (SNP) | VAF 14/38 reads (37%) | catalogued as rs564695236, COSV53738603; called by muse, mutect2, varscan2
- GRIA4 | c.2295-5882G>A | Intron (SNP) | VAF 31/31 reads (100%) | catalogued as COSV56900393; called by muse, mutect2, varscan2
- HNMT | c.137+2475G>A | Intron (SNP) | VAF 31/35 reads (89%) | catalogued as rs145915370; called by muse, mutect2, varscan2
- LGALS12 | c.-32C>T | 5'UTR (SNP) | VAF 22/97 reads (23%) | catalogued as rs780715197, COSV55370574; called by muse, mutect2, varscan2
- RPL23A | c.210-79C>T | Intron (SNP) | VAF 92/145 reads (63%) | catalogued as rs1184273037, COSV99411820; called by muse, mutect2, varscan2
- SALL4 | c.-1C>A | 5'UTR (SNP) | VAF 19/89 reads (21%) | catalogued as COSV99409710; called by muse, mutect2, varscan2
- SSPOP | n.1728C>T | RNA (SNP) | VAF 22/57 reads (39%) | catalogued as rs992526364, COSV100022349, COSV100022745; called by muse, varscan2
- ZNF99 | c.*1093C>A | 3'UTR (SNP) | VAF 25/109 reads (23%) | catalogued as rs773613310, COSV68055924; called by muse, mutect2, varscan2
